Gene-level copy-number profile of tumor specimen TCGA-BK-A139-02A from TCGA case TCGA-BK-A139, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.1 years (27,077 days).
Specimen TCGA-BK-A139-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.566ca050-688b-48d2-813a-fe1a753eabca.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BK-A139-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 365 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/83294d8a-c027-4b7b-8506-d5b822d2f166

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 1,516; copy number 2: 21,886; copy number 3: 18,049; copy number 4: 14,073; copy number 5: 2,470; copy number 6: 546; copy number 7: 373; copy number 8: 410; copy number 9: 161; copy number 10: 3; copy number 11: 8; copy number 13: 20; copy number 14: 146; copy number 15: 40; copy number 18: 35; copy number 24: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BK-A139-02A-11D-A27O-01): tumor purity 0.58, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,951 genes in 64 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–10,181,239, 345 genes, copy number 5–6 (broad region; genes not listed).
- chr1:24,119,771–24,673,281, 14 genes, copy number 5–8 (within-gene range 3–8): IL22RA1, IFNLR1, LINC02800, GRHL3-AS1, GRHL3, STPG1, NIPAL3, RCAN3AS, RCAN3, NCMAP-DT, NCMAP, AL445686.1, Y_RNA, SRRM1.
- chr1:43,525,187–44,031,467, 20 genes, copy number 5 (within-gene range 3–5): PTPRF, KDM4A, AL451062.2, KDM4A-AS1, ST3GAL3, ST3GAL3-AS1, U6, AL451062.1, MIR6079, SHMT1P1, ARTN, AL357079.1, AL357079.3, IPO13, AL357079.2, DPH2, ATP6V0B, B4GALT2, CCDC24, SLC6A9.
- chr1:148,330,271–150,518,032, 88 genes, copy number 5 (broad region; genes not listed).
- chr1:171,083,565–171,824,959, 28 genes, copy number 6: BX284613.1, FMO3, MIR1295A, MIR1295B, FMO6P, FMO2, AL021026.1, FMO1, Y_RNA, HMGB1P11, FMO4, TOP1P1, SRP14P4, GM2AP2, CYCSP53, PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2.
- chr1:179,926,641–181,191,149, 26 genes, copy number 8: AL353708.2, AL353708.1, CEP350, RPSAP16, AL590632.1, AL390718.1, QSOX1, LHX4, ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA, XPR1, U6, LINC02816, KIAA1614, AL162431.1, KIAA1614-AS1, AL162431.2, AL162431.3, STX6, MR1, IER5, LINC01732, AL358393.1.
- chr2:85,318,020–85,791,383, 32 genes, copy number 5 (within-gene range 3–5): TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, PARTICL, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68, SFTPB, GNLY, GPR160P1, RNU1-38P, ATOH8, MIR6071.
- chr2:113,022,089–113,425,548, 10 genes, copy number 6 (within-gene range 4–6): IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1.
- chr2:121,040,610–121,809,962, 17 genes, copy number 6: Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823.
- chr2:158,658,337–159,232,659, 14 genes, copy number 6 (within-gene range 4–6): PKP4-AS1, AC005042.1, AC005042.2, DAPL1, AC064843.1, OR7E89P, OR7E28P, OR7E90P, RNU2-21P, TANC1, BTF3L4P2, RNU6-580P, GSTM3P2, MIR6888.
- chr2:176,664,676–178,108,339, 37 genes, copy number 6 (within-gene range 4–6): RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P, AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS, TTC30B, AC073834.1, TTC30A, PDE11A, PDE11A, PDE11A-AS1, AC011998.2, API5P2, SDHDP5, RNU6-629P.
- chr3:28,574,791–30,010,391, 7 genes, copy number 5: RBMS3, RBMS3-AS3, MESTP4, RPS12P5, RBMS3-AS2, MTND4LP9, RBMS3-AS1.
- chr3:86,235,321–90,257,415, 36 genes, copy number 5 (within-gene range 2–5): RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P.
- chr3:188,688,781–198,222,513, 218 genes, copy number 5 (broad region; genes not listed).
- chr4:25,504,997–25,863,760, 13 genes, copy number 5 (within-gene range 3–5): AC133963.1, AC105290.1, RNU7-126P, AC092436.1, SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3.
- chr4:53,377,839–59,630,324, 109 genes, copy number 6–13 (within-gene range 3–13) (broad region; genes not listed).
- chr4:183,380,345–187,444,298, 98 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5–9 (broad region; genes not listed).
- chr6:99,271,168–100,464,921, 19 genes, copy number 5 (within-gene range 4–5): FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1, PRDM13, Y_RNA, MCHR2, MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1, SIM1, SIM1-AS1.
- chr7:32,427,901–64,375,584, 601 genes, copy number 5 (broad region; genes not listed).
- chr7:97,437,518–109,960,184, 332 genes, copy number 5–7 (broad region; genes not listed).
- chr7:111,394,875–112,896,625, 21 genes, copy number 5 (within-gene range 4–5): AC003989.2, AC003989.1, DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1, ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1.
- chr8:38,142,700–39,417,378, 36 genes, copy number 15: STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5.
- chr8:53,966,552–54,479,963, 17 genes, copy number 6: TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7.
- chr8:56,638,894–73,747,708, 250 genes, copy number 5–9 (within-gene range 3–27) (broad region; genes not listed).
- chr9:135,447,446–138,203,325, 152 genes, copy number 5 (broad region; genes not listed).
- chr10:63,110,139–63,625,128, 11 genes, copy number 5 (within-gene range 3–5): RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3.
- chr10:122,879,681–126,798,708, 73 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr11:65,333,852–65,797,219, 43 genes, copy number 6 (within-gene range 3–6): DPF2, TIGD3, AP000944.1, SLC25A45, FRMD8, NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B, EHBP1L1, KCNK7, MAP3K11, PCNX3, MIR4690, SIPA1, MIR4489, RELA, RELA-DT, RN7SL309P, KAT5, RNASEH2C, KRT8P26, AP001266.2, AP5B1, OVOL1, OVOL1-AS1, AP001266.1.
- chr12:66,767–6,342,114, 146 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:67,902,208–69,408,735, 15 genes, copy number 6: OR7E111P, OR7E33P, AL590027.1, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1.
- chr14:35,219,023–35,404,749, 8 genes, copy number 5: MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA.
- chr15:79,894,502–81,149,179, 41 genes, copy number 5: AC015871.6, ST20, AC015871.7, AC015871.3, ST20-AS1, AC015871.8, AC015871.1, BCL2A1, AC015871.2, AC015871.5, AC092701.1, Metazoa_SRP, ZFAND6, FAH, AC087761.1, CTXND1, LINC00927, AC016705.2, ARNT2, AC016705.1, AC016705.3, AC108451.1, AC108451.2, MIR5572, RNU6-380P, ABHD17C, AC023302.1, AC023302.2, CEMIP, MIR549A, AC027808.1, AC027808.2, MESD, AC068870.1, MIR4514, AC068870.2, TLNRD1, AC068870.4, CFAP161, AC068870.3, ANP32BP3.
- chr15:90,001,324–90,369,146, 26 genes, copy number 6: ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774.
- chr17:47,694,081–48,606,414, 48 genes, copy number 6: TBKBP1, TBX21, OSBPL7, MRPL10, LRRC46, SCRN2, SP6, AC018521.3, AC018521.7, AC018521.5, SP2, SP2-AS1, AC018521.6, PNPO, AC018521.1, AC018521.2, PRR15L, CDK5RAP3, AC018521.4, COPZ2, MIR152, NFE2L1-DT, NFE2L1, AC004477.1, AC004477.2, CBX1, RNU6-1201P, SNX11, SKAP1, MIR1203, SKAP1-AS1, RNU6-1152P, THRA1/BTR, AC036222.2, U3, AC036222.1, Y_RNA, HOXB1, HOXB2, HOXB-AS1, HOXB3, HOXB-AS3, HOXB-AS2, HOXB4, AC103702.1, MIR10A, HOXB5, HOXB6.
- chr18:54,406,889–54,959,461, 11 genes, copy number 9 (within-gene range 1–9): SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68.
- chr19:8,302,127–11,197,791, 152 genes, copy number 5–8 (broad region; genes not listed).
- chr20:31,514,410–32,050,705, 27 genes, copy number 6 (within-gene range 4–6): HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482.
- chr20:33,217,310–34,269,344, 33 genes, copy number 5 (within-gene range 3–5): BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B, TPM3P2, PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1.
- chr20:49,903,391–50,429,483, 20 genes, copy number 5: SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P.

Autosomal genes at a single copy (total copy number 1): 1,315. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
